Somatic mutation profile of tumor specimen 0DT7X5 from CCDI case PBCJAZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,484 days).
Specimen 0DT7X5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3371159-78fd-4d70-88a0-e0fb59707bd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT7WT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76eee99a-4fea-4f9f-bf4f-d7f405f2e07b

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 439/1154 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 311/817 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 126/505 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.374_375+3del p.X125_splice | Splice Site (DEL) | VAF 185/394 reads (47%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ARHGEF17 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 201/611 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs1450743701; called by muse, mutect2, varscan2
- CACNB1 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 79/693 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59999033; called by muse, mutect2, varscan2
- H2BW2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 262/329 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1199937421; called by muse, mutect2, varscan2
- KIFC3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 154/662 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs1300503480; called by muse, mutect2, varscan2
- NAA38 | c.112G>A p.A38T (on ENST00000575771 / NM_001320925.2; = p.A86T on NM_032356.5) | Missense Mutation (SNP) | VAF 183/341 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs1222762250; called by muse, mutect2, varscan2
- ADAMTS12 | c.3198G>C p.Q1066H | Missense Mutation (SNP) | VAF 72/820 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2
- ADH7 | c.54+1G>A p.X18_splice | Splice Site (SNP) | VAF 267/1762 reads (15%) | called by muse, mutect2, varscan2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 44/1940 reads (2%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CDC42 | c.384dup p.L129Tfs*15 | Frame Shift Ins (INS) | VAF 408/1614 reads (25%) | called by mutect2, pindel, varscan2
- DNAH7 | c.6061T>C p.S2021P | Missense Mutation (SNP) | VAF 222/1715 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR52K2 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 637/2174 reads (29%) | called by muse, mutect2, varscan2
- PDE7A | c.1015A>T p.R339* (on ENST00000401827 / NM_001242318.3; = p.R313* on NM_002603.4) | Nonsense Mutation (SNP) | VAF 140/1730 reads (8%) | called by muse, mutect2
- USP19 | c.2932C>A p.P978T | Missense Mutation (SNP) | VAF 125/414 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CA6 | c.288C>T p.R96= | Silent (SNP) | VAF 389/828 reads (47%) | called by muse, mutect2, varscan2
- MAP3K21 | c.324G>T p.P108= | Silent (SNP) | VAF 28/478 reads (6%) | catalogued as rs935700844; called by muse, mutect2
- SMIM10L2B | c.141C>T p.F47= | Silent (SNP) | VAF 28/388 reads (7%) | called by muse, mutect2
- HDLBP | c.*1209G>A | 3'UTR (SNP) | VAF 105/401 reads (26%) | called by muse, mutect2, varscan2
- PSD4 | c.2624+58C>A | Intron (SNP) | VAF 149/449 reads (33%) | called by muse, mutect2, varscan2
